Surgical pathology report (de-identified scan), TCGA case TCGA-26-1443, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-1443-01A (Primary Tumor).

[page 1 of 2]
Case Type: [REDACTED]
Accession #: [REDACTED]
Name: [REDACTED]
MRN: [REDACTED]
Pt. Location: [REDACTED]
Date Received: [REDACTED]
Date of Collection: [REDACTED]
Ref. MD: [REDACTED]

26-1443

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Left frontal brain tumor (88307) A. Frozen Section
Charge (88331) B. Left frontal brain tumor (88307)

CLINICAL HISTORY: [REDACTED] with left frontal lesion shown to be glioma by biopsy.

GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name and hospital #:

- A. Left frontal brain tumor
- B. Left frontal brain tumor

A. The specimen is received fresh, labeled "left frontal brain tumor," and consists of a 3.5 x 2.0 x 1.0 cm aggregate of red-tan to beige soft tissue pieces. A representative portion is submitted for frozen section. Frozen section diagnosis, "malignant glioma, most likely glioblastoma." By [REDACTED]. The frozen section tissue is submitted entirely for permanent processing in cassette FSA1 and a representative portion was added to the [REDACTED] and then the remaining tissue was submitted in cassettes A2 and A3. ([REDACTED])

B. The specimen is received fresh, labeled "left frontal brain tumor," and consists of a 0.8 x 0.8 x 0.6 cm aggregate of beige to red-tan soft tissue pieces. All of which are submitted in cassette B1. ([REDACTED])

DIAGNOSIS:

- A. "Left frontal brain tumor", biopsy:
Glioblastoma multiforme (WHO Grade IV astrocytoma).
- B. "Left frontal brain tumor", resection:
Glioblastoma multiforme (WHO Grade IV astrocytoma).

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]
ICD9 Codes: 191.9

[REDACTED]

[REDACTED]

[REDACTED]

[page 2 of 2]
[REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Pathologist

Electronically signed [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 1168b9d5-8f5e-4169-8e3c-5ec3157a6ca9 (TCGA-26-1443.EC9EE159-997D-408D-8248-AD95701AB2ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).